Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NG-01A (Primary Tumor).

DIAGNOSIS:

A. Gallbladder, cholecystectomy: Chronic cholecystitis. A single cystic duct lymph node is benign.

B. Liver, right, partial hepatectomy: Well-to-moderately differentiated grade 2 (of 4) hepatocellular carcinoma is identified forming a dominant mass (6.8 x 5.9 x 4.1 cm) with one satellite mass (0.2 x 0.2 x 0.2 cm). The tumor is confined to the liver. The liver parenchyma resection margin is negative for tumor (minimum tumor free margin, 0.9 cm). Macroscopic large vessel invasion is absent. Microscopic large vessel invasion is present. No regional lymph nodes are identified.

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver, C22.0

9/12/24/12

Source: NCI Genomic Data Commons file 25fecba3-8fd7-49dd-8700-4505bbce7d64 (TCGA-DD-A4NG.4E4F148F-7C70-43DE-802E-271078BDFB4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).